Gene-level copy-number profile of tumor specimen TCGA-AG-3601-01A from TCGA case TCGA-AG-3601, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-AG-3601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b4adf655-538d-4634-965b-a15f134b9078.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3601-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e98b06d-c48d-448f-928e-881385641b03

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 169; copy number 2: 8,803; copy number 3: 32,309; copy number 4: 12,398; copy number 5: 3,074; copy number 6: 1,704; copy number 7: 191; copy number 8: 1,089; copy number 11: 60; copy number 70: 1; copy number 85: 9; copy number 90: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3601-01): tumor purity 0.76, ploidy 3.39, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,522,081–14,636,524, 3 genes: AL121582.1, RNF11P2, MACROD2-IT1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,351 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:138,347,648–138,889,957, 11 genes, copy number 70–90: MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3.
- chr9:32,629,454–34,397,810, 79 genes, copy number 8 (broad region; genes not listed).
- chr9:35,360,540–38,068,687, 97 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr9:64,810,865–66,745,929, 41 genes, copy number 8: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, FO082814.1, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, FP326651.1, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, AL513478.2, AL513478.3, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr9:66,879,454–66,879,940, 1 gene, copy number 8: BX664608.1.
- chr20:25,919,499–64,313,132, 931 genes, copy number 8 (broad region; genes not listed).
- chr22:15,290,718–19,527,545, 191 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
